Somatic mutation profile of tumor specimen TCGA-QU-A6IP-01A (aliquot TCGA-QU-A6IP-01A-11D-A31L-08) from TCGA case TCGA-QU-A6IP, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.3 years (24,212 days).
Specimen TCGA-QU-A6IP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64da79f8-6425-4523-a53a-fa758a22538b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QU-A6IP-10A (Blood Derived Normal), aliquot TCGA-QU-A6IP-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2fc0d336-d655-433d-94b9-f6aca076c0a2

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 8, Silent 4, Frame Shift Ins 1, Frame Shift Del 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CARD6 | c.2656A>G p.I886V | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV54567072; called by muse, mutect2, varscan2
- FAF1 | c.1030A>G p.R344G | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65637183; called by muse, mutect2, varscan2
- GUF1 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs775500827, COSV55782882; called by muse, mutect2, varscan2
- NXF3 | c.637C>T p.Q213* | Nonsense Mutation (SNP) | VAF 77/152 reads (51%) | catalogued as COSV67704179; called by muse, mutect2, varscan2
- PLEC | c.8477G>A p.R2826H (on ENST00000322810 / NM_201380.4; = p.R2716H on NM_000445.5) | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs782161008, COSV59652677; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- PROX1 | c.1442G>A p.R481H | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs1214737525, COSV54780598; called by muse, mutect2, varscan2
- PTGR2 | c.748A>G p.I250V | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV50866187; called by muse, mutect2, varscan2
- TNXB | c.6344C>T p.T2115M (on ENST00000647633; = p.T1868M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.046); catalogued as rs1188559992, COSV64472694; called by muse, mutect2
- TTC21A | c.3944G>A p.R1315Q | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs764641145, COSV56188845; called by muse, mutect2, varscan2
- ARMC5 | c.1012_1014del p.N338del | In Frame Del (DEL) | VAF 8/75 reads (11%) | called by mutect2, pindel
- ATE1 | c.927_928dup p.P310Rfs*47 | Frame Shift Ins (INS) | VAF 13/81 reads (16%) | called by mutect2, pindel, varscan2
- ITPR2 | c.7372del p.S2458Hfs*33 | Frame Shift Del (DEL) | VAF 18/73 reads (25%) | called by mutect2, pindel, varscan2
- OR10G4 | c.634C>T p.L212= | Silent (SNP) | VAF 24/129 reads (19%) | catalogued as COSV57978178; called by muse, mutect2
- PRB4 | c.669G>A p.K223= | Silent (SNP) | VAF 44/182 reads (24%) | catalogued as COSV54397774; called by muse, mutect2, varscan2
- RFX1 | c.1002C>T p.A334= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs778536461, COSV54330874; called by muse, mutect2, varscan2
- RYR3 | c.6771C>T p.D2257= | Silent (SNP) | VAF 40/140 reads (29%) | catalogued as COSV63109703; called by muse, mutect2, varscan2
